Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2NH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2NH-06A (Metastatic).

ADDENDA:
Addendum

MOLECULAR ANATOMIC PATHOLOGY TESTING:

BRAF mutation NOT identified.

NOTE:

The quantity and quality of the isolated DNA was acceptable for testing.

FINAL DIAGNOSIS:

SOFT TISSUE AND LYMPH NODES, RIGHT AXILLARY LYMPH NODE DISSECTION -

- A. METASTATIC MELANOMA IN THREE OUT OF EIGHTEEN LYMPH NODES.
- B. EXTRACAPSULAR SPREAD PRESENT. LARGEST LYMPH NODE 3.4 CM.

COMMENT:

BRAF ordered on positive lymph node.

Collection Date:

ICB-0-3

Melanoma, NOS 8/20/3

Site: lymph node, axillary

277.3

lw 8/19/11

lw 8/19/11

Source: NCI Genomic Data Commons file 8f1a8c20-bcac-4ede-afe7-d65a6ee4ea3f (TCGA-ER-A2NH.875D53B1-DFAE-4DA3-84B0-70B14B280EA1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).